Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1M7, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1M7-01A (Primary Tumor).

1CD-0-3
Carcinoma, Squamous cell, NOS 8070/3
Site: cervix, NOS C53.9 2/24/11

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: F

DOB: [REDACTED]

Service: Gynecology

Location: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

Physician(s): [REDACTED], M.D.

DIAGNOSIS:

UTERUS, CERVIX, RADICAL HYSTERECTOMY

- SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, 2.5 CM IN GREATEST DIMENSION
- TUMOR INVADES TO A DEPTH OF 0.7 CM (TOTAL WALL THICKNESS 1.8 CM)
- NO LYMPH VASCULAR SPACE INVASION IS IDENTIFIED
- RESECTION MARGINS ARE FREE OF CARCINOMA

PARAMETRIA, RADICAL HYSTERECTOMY

- NO CARCINOMA IDENTIFIED

LYMPH NODES, PARAMETRIA, RADICAL HYSTERECTOMY

- NO CARCINOMA IDENTIFIED IN ELEVEN LYMPH NODES (0/11)

VAGINA, RADICAL HYSTERECTOMY

- NO DYSPLASIA OR CARCINOMA IDENTIFIED

UTERUS, ENDOMETRIUM, RADICAL HYSTERECTOMY

- SECRETORY ENDOMETRIUM

UTERUS, MYOMETRIUM, RADICAL HYSTERECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

OVARIES, RIGHT AND LEFT, SALPINGO-OOPHORECTOMY

- PARA-OVARIAN ADHESIONS

FALLOPIAN TUBES, RIGHT AND LEFT, SALPINGO-OOPHORECTOMY

- PERITUBAL ADHESIONS
- HYDROSALPINX

LYMPH NODE, RIGHT EXTERNAL ILIAC, EXCISION (FS1)

- NO CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1)

LYMPH NODES, RIGHT EXTERNAL ILIAC, EXCISION

- NO CARCINOMA IDENTIFIED IN FIVE LYMPH NODES (0/5)

Source: NCI Genomic Data Commons file cc4e6211-d30b-43c5-89cb-8963344950de (TCGA-C5-A1M7.ABC2B2A7-E5EE-4198-80E0-E64A6305B47A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).